Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3JA, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3JA-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcv
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Previous melanoma.
Previous right inguinal dissection (
Now, recurrent right pelvic lymph node.

Right pelvic dissection

Operation: Redo pelvic dissection on right.

Specimens: (1). Tumour right lateral pelvis.

(3). Right pelvic side wall.

(2). Tumour from iliac bifurcation (right).

(4). Common iliac node right side.

ICD-0-3

Melanoma, NOS 8720/3

Site: Subcutaneous tissue,
NOS C49.9

W 6/10/12

MACROSCOPIC DESCRIPTION

(Dr

Four specimens were received.

1. "TUMOUR RIGHT LATERAL PELVIS". Please note specimen was received fresh and portion of 20mm taken for

An unorientated piece of fatty tissue 35 x 30 x 20mm containing a multinodular cream tumour 20 x 20 x 18mm. Margins inked blue. Serial sectioning shows tumour nodules abutting the blue inked tissue margin. Two transverse sections through remainder of tumour all embedded in two blocks (A-B).

2. "TUMOUR FROM ILIAC BIFURCATION (RIGHT)". An irregular, elongated piece of fatty tissue 60 x 20 x 10mm. Margins inked blue. The cut section shows an irregular, pale firm area (?tumour within node, ?tumour within soft tissue, ?fibrosis) 20 x 10 x 6mm. A separate small lymph node was identified 8mm across. A possible small other lymph node was identified up to 3mm across.

- A. Irregular firm area trisected and all embedded.
- B. One lymph node.
- C. Possible small lymph node.

3. "RIGHT PELVIS SIDE WALL". Seven irregular pieces of grey fibrous tissue from 5 to 10mm across.

- A. Smaller fragments, all embedded.
- B. Three larger fragments.

4. "COMMON ILIAC NODE RIGHT SIDE". A lymph node 12 x 8 x 6mm with attached fat up to 5mm across. Bisected and all embedded in one block.

MICROSCOPIC REPORT

1-4. The re-do (R) pelvic dissection shows **metastatic malignant melanoma**.

Melanoma is present in blocks 1A, 1B, 2A, 3A, 3B. There are 3 uninvolved nodes also included (blocks 2B, 2C, 4A).

Old surgical scar is seen in block 2C.

The melanoma has a pleomorphic epithelioid cytomorphology, minimal pigment, mitotic rate 3/mm2. Immunohistochemically it stains for S100 (2-3+ cytoplasmic), Melan A, (2+ cytoplasmic), while mostly negative with just focal 1+ cytoplasmic.

No TILs or regression.

Tumour cells are seen at the inked specimen edge in blocks 1A, 1B, 2A, and at the edge of fragments in specimen 3.

Print

Page 1 of 2

Check	Yes
Primary Times Site Discrepancy	
Histology Discrepancy	
Prior Metastatic History	
Care is (check):	
Reviewed Initials	

[page 2 of 2]
Requested by

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

COMMENT

No kidney received in Pathology.

SUMMARY

(R) pelvic node dissection (re-do) - Metastatic MALIGNANT MELANOMA.

REPORTED BY:

Source: NCI Genomic Data Commons file 6f1d6eb1-ea32-4355-a864-68d6c259df0e (TCGA-EE-A3JA.9AD98E02-1774-4BA5-9162-141C95B546F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).